FM case AD3168 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Specialized Gonadal Neoplasms; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/d18ee049-ecb4-4306-92e0-b93e94f7cfdd

Female, 57.1 years: Granulosa cell tumor, NOS (ICD-O-3 8620/1) of the ovary; metastasis biopsied or resected from the peritoneum. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Metastatic.
